Gene-level copy-number profile of tumor specimen HCM-SANG-0310-C15-01A from HCMI case HCM-SANG-0310-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G3.
Specimen HCM-SANG-0310-C15-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 60d0a015-71d9-4fa0-b71c-7c3696a2e24d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0310-C15-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,723 have no estimate.
https://portal.gdc.cancer.gov/files/219c6e90-cd8e-4ab0-b8be-c127c172e61a

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 526; copy number 1: 19; copy number 2: 1,437; copy number 3: 639; copy number 4: 33,422; copy number 5: 4,417; copy number 6: 9,575; copy number 7: 3,368; copy number 8: 3,602; copy number 9: 595; copy number 10: 486; copy number 11: 613; copy number 12: 119; copy number 13: 31; copy number 14: 20; copy number 18: 6; copy number 19: 7; copy number 20: 2; copy number 26: 4; copy number 32: 3; copy number 50: 9.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:65,189,995–65,230,861, 3 genes: BMS1P12, AL512605.1, AL512605.2.
- chr10:38,601,418–38,605,609, 1 gene: ABCD1P2.
- chr10:72,730,557–72,767,052, 3 genes (within-gene range 0–4): AC016542.3, AC016542.2, AC016542.1.
- chr20:15,280,764–15,280,873, 1 gene (within-gene range 0–6): RNA5SP475.
- chr22:18,605,355–18,611,919, 3 genes: AC023490.1, RN7SKP131, RIMBP3.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,895 genes in 28 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:120,150,898–164,899,296, 915 genes, copy number 9–14 (within-gene range 7–14) (broad region; genes not listed).
- chr1:205,913,048–206,003,461, 3 genes, copy number 9: SLC26A9, AL713965.1, RAB7B.
- chr1:227,393,554–232,041,272, 151 genes, copy number 10–13 (broad region; genes not listed).
- chr2:169,810,081–169,824,931, 1 gene, copy number 14 (within-gene range 4–14): METTL5.
- chr3:129,087,569–129,326,225, 14 genes, copy number 10: RAB43, ISY1-RAB43, AC108673.2, ISY1, AC108673.3, CNBP, RPS27P12, COPG1, MIR6826, AC137695.3, HMCES, H1-10, H1-10-AS1, NUP210P3.
- chr3:194,247,638–194,260,720, 1 gene, copy number 9 (within-gene range 8–9): LINC02037.
- chr5:58,198–11,904,446, 233 genes, copy number 10 (broad region; genes not listed).
- chr5:40,240,167–41,587,787, 17 genes, copy number 11–19: LINC00604, RNU1-150P, TTC33, SNORA63, PTGER4, PRKAA1, AC008810.1, RPL37, SNORD72, CARD6, C7, RNU7-161P, AC114967.1, MROH2B, C6, PLCXD3, AC008817.1.
- chr7:5,592,816–5,606,655, 1 gene, copy number 11: FSCN1.
- chr7:7,293,508–7,293,880, 1 gene, copy number 13: AC079448.1.
- chr7:57,770,619–57,837,046, 13 genes, copy number 10: AC023141.4, AC023141.8, AC023141.5, AC023141.12, AC023141.2, AC023141.9, AC023141.11, AC023141.3, AC023141.1, AC023141.10, AC023141.6, AC023141.7, AC023141.13.
- chr7:99,472,890–99,679,998, 10 genes, copy number 9: ZNF789, ZNF394, ZKSCAN5, FAM200A, ZNF655, AC005020.2, TMEM225B, ZSCAN25, AC005020.1, CYP3A5.
- chr8:114,791,653–137,105,458, 280 genes, copy number 9–11 (broad region; genes not listed).
- chr9:114,323,056–114,398,503, 4 genes, copy number 11: ORM1, ORM2, AKNA, AL138895.1.
- chr12:38,078,529–38,329,721, 11 genes, copy number 11: AK6P2, CLUHP8, AC079460.1, AC079460.2, RNA5SP358, RNA5SP359, TUBB8P5, AC117372.1, NF1P12, Y_RNA, ALG10B.
- chr13:29,764,371–31,162,388, 36 genes, copy number 10: UBL3, Metazoa_SRP, TIMM8BP1, LINC00297, LINC00572, LINC00544, AL354674.1, LINC00365, LINC00384, LINC00385, AL157770.1, KATNAL1, RNU6-64P, PRDX2P1, LINC00427, LINC00426, AL356750.1, LINC01058, UBE2L5, HMGB1, AL353648.1, RBM22P2, MFAP1P1, PTPN2P2, USPL1, Metazoa_SRP, ALOX5AP, LINC00398, LINC00545, TEX26-AS1, MEDAG, TEX26, AL353680.1, LINC01066, WDR95P, HSPH1.
- chr13:43,883,800–44,028,526, 1 gene, copy number 10 (within-gene range 8–10): AL512506.3.
- chr13:43,908,669–44,256,596, 9 genes, copy number 10: NRAD1, DGKZP1, LINC00390, SMIM2-AS1, SMIM2, SMIM2-IT1, AL589745.2, MIR8079, AL589745.1.
- chr13:48,296,162–48,599,436, 12 genes, copy number 9: RB1-DT, RB1, PPP1R26P1, PCNPP5, AL392048.1, LPAR6, Metazoa_SRP, RCBTB2, AL157813.2, AL157813.1, LINC01077, LINC00462.
- chr13:73,054,976–73,227,260, 5 genes, copy number 9: KLF5, FABP5P1, RNU6-66P, RNU4-10P, RNY1P8.
- chr15:44,665,732–44,718,851, 3 genes, copy number 9: PATL2, Y_RNA, B2M.
- chr16:18,002,806–19,718,235, 58 genes, copy number 9–12 (within-gene range 4–12): AC091489.1, AC091489.2, AC008785.1, AC126755.3, NPIPA8, AC126755.5, PKD1P4, MIR6511A4, AC126755.4, NPIPA9, PKD1P5, MIR6770-3, Y_RNA, AC126755.2, MIR3180-3, MIR3670-3, AC126755.1, MIR3179-3, NOMO2, MIR3670-4, MIR3179-4, AC136618.2, AC136618.1, ABCC6P1, RPS15A, AC138811.2, ARL6IP1, AC138811.1, SMG1, AC092287.1, TMC7, RNU6-1340P, AC099518.4, AC099518.2, COQ7, AC099518.1, AC099518.6, ITPRIPL2, AC099518.3, AC099518.5, SYT17, AC010494.1, CLEC19A, AC130456.1, AC130456.2, AC130456.7, TMC5, AC130456.4, AC130456.3, RNU4-46P, AC130456.5, GDE1, AC130456.6, CCP110, VPS35L, AC002550.2, KNOP1, AC002550.1.
- chr16:28,749,959–29,404,029, 43 genes, copy number 10: AC145285.5, NPIPB9, AC145285.7, AC145285.2, AC145285.1, AC145285.3, AC145285.6, ATXN2L, AC133550.2, TUFM, MIR4721, SH2B1, AC133550.3, ATP2A1, ATP2A1-AS1, AC133550.1, RABEP2, CD19, NFATC2IP, AC109460.2, MIR4517, AC109460.1, SPNS1, AC109460.3, LAT, AC109460.4, NPIPB10P, AC009093.3, RRN3P2, AC009093.9, AC009093.8, AC009093.10, AC009093.2, AC009093.7, AC009093.1, AC009093.5, AC009093.4, AC009093.6, AC025279.1, AC025279.2, SNX29P2, AC025279.3, NPIPB11.
- chr16:46,850,999–46,851,254, 1 gene, copy number 14: AC007225.2.
- chr19:27,681,072–31,349,436, 64 genes, copy number 9–50 (within-gene range 6–50) (broad region; genes not listed).
- chr20:37,178,410–37,317,260, 3 genes, copy number 10 (within-gene range 6–10): RPN2, GHRH, MANBAL.
- chr20:49,503,874–49,568,137, 1 gene, copy number 12: PTGIS.
- chr22:37,550,026–37,582,616, 4 genes, copy number 9: AL022315.1, CDC42EP1, LGALS2, Metazoa_SRP.

Autosomal genes at a single copy (total copy number 1): 19. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
